Somatic mutation profile of tumor specimen TCGA-VQ-A91S-01A (aliquot TCGA-VQ-A91S-01A-11D-A410-08) from TCGA case TCGA-VQ-A91S, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIB; Tumor grade: GX; Age at diagnosis: 63.5 years (23,187 days).
Specimen TCGA-VQ-A91S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08a36774-6872-4677-80d4-015b6897dcbe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A91S-10A (Blood Derived Normal), aliquot TCGA-VQ-A91S-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76a0fe52-63a8-4d15-b7e8-d1e4baddce49

The open-access MAF lists 275 somatic variants for this specimen: 203 protein-altering or splice-affecting, 63 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 180, Silent 63, In Frame Del 7, Frame Shift Del 7, Nonsense Mutation 5, Intron 5, RNA 2, Splice Site 2, 5'UTR 1, 3'UTR 1, Frame Shift Ins 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A2M | c.3536A>C p.N1179T | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.082); catalogued as COSV100589096, COSV59390023; called by muse, mutect2, varscan2
- ABCA10 | c.4451C>T p.S1484F | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99289494; called by muse, mutect2, varscan2
- ABCA13 | c.14003T>G p.L4668R | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV68945620; called by muse, mutect2, varscan2
- ABCC9 | c.3805T>G p.L1269V | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.186); catalogued as COSV53978035, COSV99687670; called by muse, mutect2, varscan2
- ABRACL | c.154G>T p.A52S | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as COSV100866354; called by muse, mutect2, varscan2
- ACTR5 | c.1086G>C p.Q362H | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV99710292; called by muse, mutect2
- ACTR8 | c.412T>C p.S138P | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV99213930; called by muse, mutect2, varscan2
- ADAMTS14 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs763213695, COSV64599858; called by muse, mutect2, varscan2
- ADAMTS3 | c.2284C>A p.H762N | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV99712403; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2240A>C p.K747T | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54453094; called by muse, mutect2, varscan2
- AKAP12 | c.4816C>G p.Q1606E | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV99484683; called by muse, mutect2, varscan2
- ALKBH1 | c.368C>G p.S123C | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV99380827; called by muse, mutect2
- APP | c.94C>G p.P32A | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV100696344; called by muse, mutect2, varscan2
- ARMC8 | c.814G>C p.D272H (on ENST00000469044 / NM_001363941.2; = p.D258H on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.265); catalogued as COSV100627906; called by muse, mutect2, varscan2
- ARSJ | c.1021C>G p.L341V | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100193220; called by muse, mutect2, varscan2
- ASB3 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV99712643; called by muse, mutect2, varscan2
- ATOH8 | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV100092918; called by muse, mutect2
- ATP2B1 | c.767A>G p.K256R | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV99666302; called by muse, mutect2, varscan2
- BCAR1 | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs561070895, COSV50797521, COSV99366894; called by muse, mutect2, varscan2
- BCL9 | c.3768A>C p.E1256D | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV99326031; called by muse, mutect2, varscan2
- BRI3BP | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as rs769016056, COSV100413213; called by muse, mutect2, varscan2
- C1S | c.1613C>G p.P538R | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.618); catalogued as COSV100196819; called by muse, mutect2, varscan2
- C1orf94 | c.853G>T p.G285W (on ENST00000488417 / NM_001134734.2; = p.G95W on NM_032884.5) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100974994; called by muse, mutect2, varscan2
- C7orf31 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.027); catalogued as COSV99384239; called by muse, varscan2
- CASZ1 | c.1189C>A p.P397T | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.674); catalogued as rs754239516, COSV100682319, COSV59740877; called by muse, mutect2, varscan2
- CDHR3 | c.140A>C p.K47T | Missense Mutation (SNP) | VAF 51/186 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100488981; called by muse, mutect2, varscan2
- CFAP20 | c.295G>A p.V99M | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.062); catalogued as COSV99343579; called by muse, mutect2, varscan2
- CLEC9A | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV63349326, COSV63350044; called by muse, mutect2, varscan2
- CNTNAP3 | c.2479T>C p.S827P | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99905846; called by muse, mutect2, varscan2
- COL21A1 | c.157T>A p.F53I | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99780616; called by mutect2, varscan2
- COL5A3 | c.3163G>T p.G1055W | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53422417; called by muse, mutect2, varscan2
- CSMD2 | c.7255G>T p.G2419* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as COSV99596795; called by muse, mutect2, varscan2
- DAAM2 | c.2963G>A p.R988Q (on ENST00000274867 / NM_001201427.2; = p.R987Q on NM_015345.3) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.607); catalogued as rs750047168, COSV51336289, COSV51419475; called by muse, mutect2, varscan2
- DAGLB | c.177G>C p.L59F | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as rs376919352; called by muse, mutect2, varscan2
- DEDD2 | c.629G>C p.G210A | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100260400; called by muse, mutect2
- DNAH5 | c.3368T>G p.L1123R | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99455430; called by muse, mutect2, varscan2
- DPPA3 | c.174A>C p.E58D | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.237); catalogued as COSV100560041; called by muse, mutect2, varscan2
- EPHA2 | c.2206G>C p.V736L | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV100626354, COSV64453394; called by muse, mutect2, varscan2
- EPHB6 | c.325T>G p.F109V | Missense Mutation (SNP) | VAF 56/140 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101236006, COSV67421111; called by muse, mutect2, varscan2
- F2RL1 | c.565A>G p.N189D | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.363); catalogued as rs370384052; called by muse, mutect2, varscan2
- FAM171B | c.1949T>G p.L650R | Missense Mutation (SNP) | VAF 42/63 reads (67%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.961); catalogued as rs781239262, COSV100489126; called by muse, mutect2, varscan2
- FAR1 | c.724-1G>C p.X242_splice | Splice Site (SNP) | VAF 10/114 reads (9%) | catalogued as COSV100701684; called by muse, mutect2
- FILIP1 | c.1696T>C p.Y566H | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV99386373; called by muse, mutect2, varscan2
- FOXP2 | c.163C>G p.Q55E | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.953); catalogued as COSV100647525; called by muse, mutect2
- FREM1 | c.4375G>C p.D1459H | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as COSV101085712, COSV66526104; called by muse, mutect2, varscan2
- FREM2 | c.4384A>T p.R1462W | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV99751500; called by muse, mutect2, varscan2
- FTMT | c.365A>G p.E122G | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100360223, COSV100360495; called by muse, mutect2, varscan2
- FUT5 | c.204G>T p.M68I | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99399044; called by muse, mutect2, varscan2
- GLI3 | c.1469A>G p.E490G | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV101230149; called by muse, mutect2, varscan2
- GRID1 | c.406G>A p.G136S | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.282); catalogued as rs777504912, COSV100027102; called by muse, mutect2, varscan2
- GRIK2 | c.1289A>G p.N430S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV100030102; called by muse, mutect2, varscan2
- GRM5 | c.130C>A p.H44N | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100554983; called by muse, mutect2, varscan2
- HGF | c.2036G>C p.C679S | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV99738849; called by muse, mutect2, varscan2
- HIVEP1 | c.5615G>A p.R1872Q | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.013); catalogued as rs1368992008, COSV101045889; called by muse, mutect2, varscan2
- HKDC1 | c.266A>C p.K89T | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100664839; called by muse, mutect2, varscan2
- HOMER2 | c.733A>G p.K245E (on ENST00000304231 / NM_199330.3; = p.K234E on NM_004839.4) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.036); catalogued as COSV100420662; called by muse, mutect2, varscan2
- HOXC11 | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs199765463, COSV54534143; called by muse, mutect2, varscan2
- IL12RB2 | c.2257C>A p.P753T | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV99255803; called by muse, mutect2, varscan2
- ITIH6 | c.413C>G p.A138G | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.241); catalogued as COSV99514159; called by muse, mutect2, varscan2
- JOSD1 | c.347T>C p.M116T | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99320235; called by muse, mutect2, varscan2
- JUP | c.943C>T p.L315F | Missense Mutation (SNP) | VAF 29/509 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100159867; called by muse, mutect2
- KANK4 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as rs749518503, COSV62985471, COSV62986746; called by muse, mutect2, varscan2
- KCNA5 | c.767C>G p.S256W | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1179534356, COSV52904458, COSV99364295; called by muse, mutect2, varscan2
- KCNMB2 | c.377A>C p.K126T | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV100844067, COSV64202141; called by muse, mutect2, varscan2
- KIAA2026 | c.1972A>T p.K658* | Nonsense Mutation (SNP) | VAF 10/84 reads (12%) | catalogued as COSV101199251; called by muse, mutect2, varscan2
- KIF27 | c.3043A>C p.K1015Q | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.186); catalogued as COSV99927367; called by muse, mutect2, varscan2
- KLHL26 | c.1652A>G p.E551G | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99963423; called by muse, mutect2, varscan2
- KPRP | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.799); catalogued as rs1403896561, COSV64221515; called by muse, mutect2, varscan2
- LACC1 | c.605C>G p.S202C | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100354830; called by muse, mutect2, varscan2
- LAMA1 | c.5548C>A p.H1850N | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.025); catalogued as COSV101058003; called by muse, mutect2
- LAMB3 | c.1637G>A p.C546Y | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100620569; called by muse, mutect2, varscan2
- LRP1B | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs145250710; called by muse, mutect2, varscan2
- LRRK2 | c.4901T>G p.F1634C | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); catalogued as COSV100111429; called by muse, mutect2, varscan2
- MAGEA11 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.173); catalogued as COSV60756141; called by muse, mutect2, varscan2
- MAGEE1 | c.2414T>G p.L805R | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63908813, COSV63909025; called by muse, mutect2, varscan2
- MAP3K20 | c.952T>C p.W318R | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0.425); catalogued as COSV100169611; called by muse, mutect2, varscan2
- MAP9 | c.1509A>C p.E503D | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.051); catalogued as COSV100251182; called by muse, mutect2, varscan2
- MDN1 | c.11854A>C p.N3952H | Missense Mutation (SNP) | VAF 46/220 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV101021925; called by muse, mutect2, varscan2
- MEDAG | c.247C>A p.Q83K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.04); catalogued as COSV100995339; called by muse, mutect2
- MEF2B | c.74A>C p.K25T | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99365169; called by muse, mutect2, varscan2
- MEPE | c.498A>C p.E166D | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.152); catalogued as COSV100735009; called by muse, mutect2, varscan2
- MOS | c.281A>C p.K94T | Missense Mutation (SNP) | VAF 17/267 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100323065; called by muse, mutect2
- MUC16 | c.15622A>C p.S5208R | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.354); catalogued as COSV67447728, COSV67479087; called by muse, mutect2, varscan2
- MYH11 | c.3402G>C p.R1134S | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100260545, COSV55555725; called by muse, mutect2, varscan2
- NAV2 | c.6655G>A p.D2219N (on ENST00000396087 / NM_001244963.2; = p.D2160N on NM_145117.5) | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as COSV100217776; called by muse, mutect2, varscan2
- NDC1 | c.1405T>G p.Y469D | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as COSV99324051; called by muse, mutect2, varscan2
- NKAIN2 | c.584A>C p.K195T | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63721791; called by muse, mutect2, varscan2
- NPBWR2 | c.208A>T p.I70F | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV100871159; called by muse, mutect2
- NPHS1 | c.3585A>C p.E1195D | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.054); catalogued as COSV100800353; called by muse, mutect2, varscan2
- NUDT16L1 | c.460G>T p.V154F | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.078); catalogued as COSV99275027; called by muse, mutect2, varscan2
- NUP58 | c.1724C>T p.S575F | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV101098953, COSV67751441; called by muse, mutect2, varscan2
- OR10J5 | c.538A>G p.I180V | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.058); catalogued as rs951125569, COSV100604862; called by muse, mutect2, varscan2
- OR13C9 | c.712T>G p.F238V | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV99403599; called by muse, mutect2, varscan2
- OR2L2 | c.8A>C p.N3T | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV63552021; called by muse, mutect2, varscan2
- OR4A15 | c.894del p.K298Nfs*7 | Frame Shift Del (DEL) | VAF 21/132 reads (16%) | catalogued as rs781599119; called by mutect2, pindel, varscan2
- OR4C15 | c.743T>G p.F248C (on ENST00000314644; = p.F194C on NM_001001920.2) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); catalogued as COSV100116194; called by muse, mutect2, varscan2
- OR4F6 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.232); catalogued as COSV100187034; called by muse, mutect2, varscan2
- OR5M3 | c.496T>G p.F166V | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100392520, COSV56565606; called by muse, mutect2, varscan2
- OR8J3 | c.71A>G p.Q24R | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as COSV100041099; called by muse, mutect2, varscan2
- PCARE | c.2956A>T p.R986* | Nonsense Mutation (SNP) | VAF 11/64 reads (17%) | catalogued as rs772855158, COSV100527999; called by muse, mutect2, varscan2
- PCCA | c.346C>G p.P116A | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as rs1566594619, COSV100887084; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHB2 | c.180A>C p.E60D | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.019); catalogued as COSV99523708; called by muse, mutect2, varscan2
- PCDHB5 | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs1417280695, COSV99169739; called by muse, mutect2, varscan2
- PCDHGA8 | c.656A>C p.K219T | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.065); catalogued as COSV99549131; called by muse, mutect2, varscan2
- PCDHGB3 | c.1547C>T p.A516V | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs781345070, COSV53933204; called by muse, mutect2, varscan2
- PCED1A | c.103G>A p.V35M | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100642968; called by muse, mutect2
- PCSK1 | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100227312; called by muse, mutect2, varscan2
- PCSK5 | c.309C>G p.I103M | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV100950039, COSV100950836; called by muse, mutect2
- PEG3 | c.4215A>C p.E1405D | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.376); catalogued as rs776446931, COSV55629146; called by muse, mutect2, varscan2
- PGAP6 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.387); catalogued as COSV99170859; called by muse, mutect2, varscan2
- PLEKHA8 | c.889C>G p.P297A | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99322388; called by muse, mutect2
- PLXNA4 | c.3080A>T p.K1027M | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.657); catalogued as COSV100327913; called by muse, mutect2, varscan2
- PNPLA3 | c.100C>A p.P34T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99337396; called by muse, varscan2
- PPP4R4 | c.1410C>A p.S470R | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV100429127; called by muse, mutect2, varscan2
- PRAMEF10 | c.1063G>A p.V355I | Missense Mutation (SNP) | VAF 27/220 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1174936313; called by muse, mutect2, varscan2
- PRDM5 | c.198A>C p.E66D | Missense Mutation (SNP) | VAF 55/230 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV53357080; called by muse, mutect2, varscan2
- PREX2 | c.148T>A p.L50I | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.639); catalogued as COSV55750189, COSV55751655, COSV99910567; called by muse, mutect2, varscan2
- PRICKLE1 | c.971C>T p.S324L | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100566720; called by muse, mutect2, varscan2
- PRX | c.2656G>A p.E886K | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs779463585, COSV52531859, COSV99398152; called by muse, mutect2, varscan2
- QRICH2 | c.2965T>C p.F989L | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV99429858; called by muse, mutect2, varscan2
- RAD23B | c.788C>T p.T263I | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.067); catalogued as COSV100787784; called by muse, mutect2, varscan2
- RALGPS1 | c.694C>G p.Q232E | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.403); catalogued as COSV99402802; called by muse, mutect2, varscan2
- RANBP6 | c.1516C>G p.Q506E | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.138); catalogued as COSV99424500; called by muse, mutect2, varscan2
- RAPH1 | c.643G>C p.A215P | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs772560358, COSV100051432, COSV100052085; called by muse, mutect2, varscan2
- RBM34 | c.1138G>A p.V380I | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1277345399, COSV100784101; called by muse, mutect2, varscan2
- RET | c.2720A>C p.K907T | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM016243, CM1110131, COSV100394900; called by muse, mutect2, varscan2
- RGS10 | c.203dup p.D68Efs*3 (on ENST00000369101; = p.D62Efs*3 on NM_002925.3) | Frame Shift Ins (INS) | VAF 18/61 reads (30%) | catalogued as COSV64861688; called by mutect2, pindel, varscan2
- RGS3 | c.101C>A p.P34H | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.06); catalogued as COSV100466084; called by muse, mutect2, varscan2
- RICTOR | c.2170G>A p.A724T | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as COSV99705878; called by muse, mutect2
- RNASEH2B | c.929G>C p.G310A | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.037); catalogued as COSV100352450; called by muse, mutect2, varscan2
- RPLP0 | c.469G>C p.D157H | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV99935525; called by muse, mutect2, varscan2
- RRAGD | c.532A>C p.I178L | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV100784658; called by muse, mutect2, varscan2
- SAMHD1 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs559553527, CM102547, COSV99483986; called by muse, mutect2, varscan2
- SCARA5 | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs774080674, COSV100108129; called by muse, mutect2
- SCN10A | c.3269A>G p.D1090G | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101479586; called by muse, mutect2, varscan2
- SERPIND1 | c.1083C>A p.H361Q | Missense Mutation (SNP) | VAF 22/416 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.098); catalogued as rs751646741, COSV99300546; called by muse, mutect2
- SERPINH1 | c.440T>A p.V147E | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100825182; called by muse, mutect2, varscan2
- SETBP1 | c.3712G>A p.D1238N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs144087649; called by muse, mutect2, varscan2
- SETX | c.2125A>G p.T709A | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs750530263, COSV99811273; called by muse, mutect2, varscan2
- SLC10A2 | c.1022G>A p.G341E | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV55359317; called by muse, mutect2, varscan2
- SLC17A5 | c.812G>C p.R271T | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV63288861; called by muse, mutect2, varscan2
- SLC22A12 | c.1419G>C p.Q473H | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.317); catalogued as COSV100327986, COSV60574532; called by muse, mutect2, varscan2
- SNX14 | c.955T>G p.L319V (on ENST00000314673 / NM_001350535.1; = p.L275V on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100121837; called by muse, mutect2, varscan2
- SPRR3 | c.364T>G p.F122V | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.089); catalogued as COSV99768827; called by muse, mutect2, varscan2
- SPTLC3 | c.1250T>G p.L417R | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV65463363; called by muse, mutect2, varscan2
- SRP19 | c.170G>C p.G57A | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99295403; called by muse, mutect2, varscan2
- ST6GALNAC6 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 17/99 reads (17%) | PolyPhen possibly damaging (0.86); catalogued as COSV99398679; called by muse, mutect2, varscan2
- STK32A | c.170A>G p.Q57R | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.596); catalogued as COSV100097830; called by muse, mutect2
- SYT1 | c.137A>C p.K46T | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.343); catalogued as COSV54042380, COSV99695097; called by muse, mutect2, varscan2
- TBC1D4 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as COSV100884866; called by muse, mutect2, varscan2
- TBL1X | c.181T>G p.F61V | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as COSV99483311; called by muse, mutect2, varscan2
- TDRD5 | c.1087T>A p.L363I | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.671); catalogued as COSV99677485; called by muse, mutect2, varscan2
- TEX29 | c.350A>C p.K117T | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.767); catalogued as COSV99366237; called by muse, mutect2, varscan2
- TMCO3 | c.1625A>T p.E542V | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as COSV100952468; called by muse, mutect2, varscan2
- TMEM132B | c.2947T>G p.F983V | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.668); catalogued as COSV100171270; called by muse, mutect2, varscan2
- TMEM139 | c.592T>C p.C198R | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs1370204709, COSV100131330; called by muse, mutect2, varscan2
- TMEM141 | c.160A>G p.R54G | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); catalogued as COSV99264474; called by muse, mutect2, varscan2
- TMEM147 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99383200; called by muse, mutect2, varscan2
- TMEM225 | c.448T>G p.F150V | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.178); catalogued as COSV100902826; called by muse, mutect2, varscan2
- TNKS2 | c.2033G>C p.R678T | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100861180; called by muse, mutect2
- TNS3 | c.4283G>C p.S1428T | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV100236680; called by muse, mutect2, varscan2
- TOX | c.412-1G>A p.X138_splice | Splice Site (SNP) | VAF 22/60 reads (37%) | catalogued as COSV100813170, COSV63843223; called by mutect2, varscan2
- TPH2 | c.992A>C p.K331T | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV61590489, COSV61591680, COSV61594179; called by muse, mutect2, varscan2
- TPR | c.2756C>G p.S919C | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as COSV100824295; called by muse, mutect2, varscan2
- TRPC3 | c.518C>T p.A173V (on ENST00000379645 / NM_001366479.2; = p.A100V on NM_003305.2) | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.804); catalogued as rs141601839, COSV53378851; called by muse, mutect2, varscan2
- TRPM3 | c.1289T>A p.F430Y (on ENST00000357533 / NM_001366142.2; = p.F275Y on NM_020952.6) | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.349); catalogued as COSV100679139; called by muse, mutect2, varscan2
- TTC39B | c.644C>A p.S215Y | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99896351; called by muse, mutect2, varscan2
- UBR3 | c.4091G>C p.R1364T | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99775200; called by muse, mutect2, varscan2
- UGT1A6 | c.831C>G p.I277M | Missense Mutation (SNP) | VAF 34/365 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.171); catalogued as rs764583792, COSV100531290; called by muse, mutect2
- UNC80 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 44/54 reads (81%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV99781423; called by muse, mutect2, varscan2
- VWA3A | c.646G>T p.A216S | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.079); catalogued as rs1407001992, COSV101233272; called by muse, mutect2, varscan2
- WASF3 | c.468T>A p.Y156* | Nonsense Mutation (SNP) | VAF 12/55 reads (22%) | catalogued as COSV100099741; called by muse, mutect2, varscan2
- WHRN | c.1349G>T p.R450L | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.413); catalogued as COSV54332104, COSV99470670; called by muse, mutect2, varscan2
- XIRP2 | c.3678A>T p.E1226D (on ENST00000628543; = p.E1401D on NM_152381.6) | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV54696788, COSV54722905, COSV99739657; called by muse, mutect2, varscan2
- YTHDF3 | c.478A>G p.S160G | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV101572441; called by muse, mutect2
- ZFHX4 | c.438A>C p.K146N | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.996); catalogued as COSV99268942; called by muse, mutect2, varscan2
- ZNF124 | c.1048A>G p.K350E (on ENST00000543802 / NM_001297568.1; = p.K288E on NM_003431.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV100517943; called by mutect2, varscan2
- ZNF287 | c.1765G>A p.E589K | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as COSV101209456; called by muse, mutect2, varscan2
- ZNF318 | c.4416C>G p.I1472M | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.178); catalogued as COSV100546418, COSV100546588; called by muse, mutect2, varscan2
- ZNF33B | c.1230G>C p.E410D | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as COSV100847816; called by muse, mutect2
- ZNF479 | c.983A>T p.E328V | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV100483171; called by muse, mutect2, varscan2
- ZNF714 | c.494G>T p.R165I | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.047); catalogued as rs766981915, COSV99395275, COSV99395698; called by muse, mutect2, varscan2
- ZNFX1 | c.1288G>C p.V430L | Missense Mutation (SNP) | VAF 40/213 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV100871045; called by muse, mutect2, varscan2
- ZSCAN1 | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.699); catalogued as rs1409636598, COSV56606935; called by muse, varscan2
- ZXDB | c.1217C>A p.T406K | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100886103; called by muse, mutect2, varscan2
- CLIC5 | c.572_580del p.C191_F193del (on ENST00000185206 / NM_001370649.1; = p.C32_F34del on NM_016929.5) | In Frame Del (DEL) | VAF 4/47 reads (9%) | called by mutect2, pindel
- FBXW10 | c.1964_1978del p.G655_P659del | In Frame Del (DEL) | VAF 27/211 reads (13%) | called by mutect2, varscan2
- IGHV3-16 | c.149A>C p.N50T | Missense Mutation (SNP) | VAF 58/301 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGHV3-33 | c.92T>G p.V31G | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.246); called by muse, mutect2
- KHDC4 | c.1384_1398del p.R462_E466del | In Frame Del (DEL) | VAF 25/145 reads (17%) | called by mutect2, pindel, varscan2
- KIF2B | c.871_903del p.I291_A301del | In Frame Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- MIA2 | c.1471_1488del p.T491_E496del | In Frame Del (DEL) | VAF 4/29 reads (14%) | called by mutect2, pindel
- MIA3 | c.537_552del p.E180Tfs*54 | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | called by mutect2, pindel, varscan2
- MYO15A | c.5230_5253del p.S1744_A1751del | In Frame Del (DEL) | VAF 24/126 reads (19%) | called by mutect2, pindel
- OR1B1 | c.349_362del p.I117Sfs*9 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- PDZRN4 | c.963del p.Y321* (on ENST00000402685 / NM_001164595.2; = p.Y63* on NM_013377.4) | Frame Shift Del (DEL) | VAF 11/50 reads (22%) | called by mutect2, pindel*, varscan2
- PIBF1 | c.1185del p.R396Efs*30 | Frame Shift Del (DEL) | VAF 13/108 reads (12%) | called by pindel, varscan2
- PRDM13 | c.586_601del p.A196Rfs*61 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | called by mutect2, varscan2
- PRKCI | c.876_881del p.D292_D293del | In Frame Del (DEL) | VAF 7/47 reads (15%) | called by mutect2, pindel, varscan2
- ROCK2 | c.2458_2477del p.L820Vfs*6 | Frame Shift Del (DEL) | VAF 21/78 reads (27%) | called by mutect2, pindel, varscan2
- TRAV3 | c.259A>C p.N87H | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- TRIOBP | c.3268_3273dup p.D1090_T1091dup | In Frame Ins (INS) | VAF 14/80 reads (18%) | called by mutect2, varscan2
- UGT8 | c.1019G>A p.W340* | Nonsense Mutation (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- ADGRE2 | c.2343C>T p.L781= | Silent (SNP) | VAF 42/145 reads (29%) | catalogued as COSV59692891; called by muse, mutect2, varscan2
- ADGRL3 | c.3291T>G p.T1097= (on ENST00000506720 / NM_001322402.2; = p.T1029= on NM_015236.6) | Silent (SNP) | VAF 23/93 reads (25%) | catalogued as COSV101547444; called by muse, mutect2, varscan2
- ANGPT4 | c.1059C>T p.F353= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs112090528; called by muse, mutect2, varscan2
- AOC3 | c.915T>C p.P305= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV99520493; called by muse, mutect2, varscan2
- ATP13A4 | c.2359A>C p.R787= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as COSV100710832; called by muse, mutect2, varscan2
- BANK1 | c.1737T>G p.T579= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV100537016; called by muse, mutect2, varscan2
- CACNA1B | c.1926C>T p.P642= | Silent (SNP) | VAF 71/226 reads (31%) | catalogued as COSV99500519; called by muse, mutect2, varscan2
- CCDC116 | c.996C>G p.G332= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV99489031; called by muse, mutect2, varscan2
- CFAP61 | c.573A>G p.E191= | Silent (SNP) | VAF 31/169 reads (18%) | catalogued as COSV99846991; called by muse, mutect2, varscan2
- CHD5 | c.684C>T p.V228= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as rs768857681, COSV52416125; called by muse, mutect2, varscan2
- CIB3 | c.402A>G p.K134= | Silent (SNP) | VAF 22/99 reads (22%) | catalogued as COSV99521950; called by muse, mutect2, varscan2
- COL15A1 | c.495C>T p.A165= | Silent (SNP) | VAF 10/108 reads (9%) | catalogued as COSV100898084; called by muse, mutect2
- CPD | c.2811A>G p.K937= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV99853383; called by muse, mutect2, varscan2
- DDX4 | c.1449T>G p.T483= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV100737837; called by muse, mutect2, varscan2
- DSCAM | c.834G>T p.L278= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV101261750; called by muse, mutect2, varscan2
- EPHA5 | c.136C>T p.L46= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV99901917; called by muse, mutect2
- ETNPPL | c.528A>G p.G176= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV99625736; called by muse, mutect2, varscan2
- FGD6 | c.3795G>A p.L1265= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV100676907; called by muse, mutect2, varscan2
- GIGYF2 | c.3579G>A p.E1193= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as COSV101004668; called by muse, mutect2, varscan2
- GPR137 | c.1245G>A p.P415= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as rs769279910, COSV100464601; called by muse, mutect2, varscan2
- GTPBP3 | c.429C>T p.F143= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as rs145625259, COSV50201033; called by muse, mutect2, varscan2
- IHO1 | c.63G>A p.K21= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as rs1305860695, COSV56508854, COSV99606692; called by muse, mutect2, varscan2
- IL10 | c.459C>T p.G153= | Silent (SNP) | VAF 23/94 reads (24%) | catalogued as COSV100894773; called by muse, mutect2, varscan2
- IL17RD | c.1428C>T p.I476= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs748920332, COSV56338565; called by muse, mutect2, varscan2
- KCNK9 | c.363A>G p.T121= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs780561134, COSV100271879; called by muse, mutect2, varscan2
- KLHL28 | c.1044T>G p.T348= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as rs763226531, COSV100753344; called by muse, mutect2, varscan2
- LIPN | c.1059C>G p.A353= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV101356249; called by muse, mutect2, varscan2
- LMNA | c.867C>T p.H289= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as rs780415585, COSV100738712; ClinVar: uncertain significance; called by muse, mutect2
- MIGA1 | c.711T>C p.D237= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as COSV100889826; called by muse, mutect2, varscan2
- MKS1 | c.651C>G p.G217= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV100439863; called by muse, mutect2, varscan2
- MSC | c.399C>T p.S133= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as COSV100335975; called by muse, mutect2, varscan2
- MUC16 | c.25554C>A p.T8518= | Silent (SNP) | VAF 32/130 reads (25%) | catalogued as rs755801605, COSV101202162; called by muse, mutect2, varscan2
- NELFCD | c.1566C>T p.V522= (on ENST00000602795; = p.V504= on NM_198976.4) | Silent (SNP) | VAF 32/147 reads (22%) | catalogued as COSV99413763; called by muse, mutect2, varscan2
- NLK | c.1308A>C p.T436= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV101311424, COSV69410513; called by muse, mutect2, varscan2
- NUP98 | c.4614C>T p.T1538= (on ENST00000359171 / NM_001365126.1; = p.T1521= on NM_016320.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as rs901407301, COSV100263692; called by muse, mutect2, varscan2
- OBI1 | c.18G>A p.Q6= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs762047001, COSV99932681; called by muse, mutect2, varscan2
- OR2T1 | c.312T>G p.L104= | Silent (SNP) | VAF 47/123 reads (38%) | catalogued as COSV100822366; called by muse, mutect2, varscan2
- OR5T2 | c.681T>G p.S227= | Silent (SNP) | VAF 32/157 reads (20%) | catalogued as COSV57588476, COSV57589308, COSV57590451; called by muse, mutect2, varscan2
- OSM | c.429C>A p.I143= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as rs763555458, COSV53162140, COSV99304353; called by muse, mutect2, varscan2
- PCSK5 | c.3906C>A p.V1302= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as rs765944049, COSV101377745; called by muse, mutect2, varscan2
- PKDREJ | c.2556C>A p.T852= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as COSV99479667; called by muse, mutect2, varscan2
- PLEKHG5 | c.1785G>A p.V595= (on ENST00000400915 / NM_001042663.3; = p.V558= on NM_020631.6) | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV100557231; called by muse, mutect2, varscan2
- PRICKLE2 | c.2541A>C p.L847= (on ENST00000295902; = p.L791= on NM_198859.4) | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV99898202; called by muse, mutect2, varscan2
- PTCH1 | c.3412C>T p.L1138= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV100110327; called by muse, mutect2, varscan2
- PTGFR | c.726T>C p.S242= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV66114263; called by muse, mutect2, varscan2
- PTPA | c.1050G>C p.L350= (on ENST00000337738 / NM_178001.2; = p.L315= on NM_021131.5) | Silent (SNP) | VAF 5/78 reads (6%) | catalogued as COSV100534226; called by muse, mutect2
- RGS8 | c.312G>A p.K104= (on ENST00000367556 / NM_001369564.2; = p.K122= on NM_033345.3) | Silent (SNP) | VAF 20/180 reads (11%) | catalogued as rs779576565, COSV99277020; called by muse, mutect2, varscan2
- RIDA | c.198G>A p.L66= | Silent (SNP) | VAF 9/140 reads (6%) | catalogued as COSV99645380, COSV99645389; called by muse, mutect2
- SLAMF8 | c.270C>A p.L90= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV99223140; called by muse, mutect2
- SOX7 | c.915G>A p.P305= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs1445112757, COSV58732007; called by mutect2, varscan2
- SPTA1 | c.2277T>G p.P759= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV100935768, COSV63754163; called by muse, mutect2, varscan2
- STAM | c.1191T>C p.S397= | Silent (SNP) | VAF 30/91 reads (33%) | catalogued as COSV101098416; called by muse, mutect2, varscan2
- STXBP5L | c.985C>T p.L329= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as rs756271385, COSV99876857; called by muse, mutect2, varscan2
- TBK1 | c.303T>C p.P101= | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as COSV100538485; called by muse, mutect2, varscan2
- TPCN1 | c.1938C>T p.V646= | Silent (SNP) | VAF 52/243 reads (21%) | catalogued as rs929533390, COSV100137184; called by muse, mutect2, varscan2
- TRAV14DV4 | c.274A>C p.R92= | Silent (SNP) | VAF 26/87 reads (30%) | called by muse, mutect2, varscan2
- TRIM36 | c.979C>T p.L327= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as rs1461947166, COSV99142889; called by muse, mutect2, varscan2
- UBASH3A | c.900T>A p.G300= | Silent (SNP) | VAF 21/80 reads (26%) | catalogued as COSV52310836, COSV99370077; called by muse, mutect2, varscan2
- USP32 | c.4725G>C p.L1575= | Silent (SNP) | VAF 36/99 reads (36%) | catalogued as COSV100343062; called by muse, mutect2, varscan2
- ZAN | c.2217C>A p.T739= | Silent (SNP) | VAF 15/144 reads (10%) | catalogued as COSV100770554; called by muse, mutect2
- ZDHHC18 | c.588C>G p.T196= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV100938886; called by muse, mutect2, varscan2
- ZIM2 | c.915T>C p.D305= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as COSV99690841; called by muse, mutect2, varscan2
- ZSCAN22 | c.747T>C p.D249= | Silent (SNP) | VAF 39/154 reads (25%) | catalogued as rs1216094324, COSV100308551; called by muse, mutect2, varscan2
- ANK2 | c.*1A>C | 3'UTR (SNP) | VAF 15/67 reads (22%) | catalogued as COSV100004732; called by muse, mutect2, varscan2
- ASB11 | c.181+957G>A | Intron (SNP) | VAF 17/53 reads (32%) | catalogued as COSV100363577; called by muse, mutect2, varscan2
- DCHS2 | n.8194T>G | RNA (SNP) | VAF 8/27 reads (30%) | catalogued as COSV100602852; called by muse, mutect2, varscan2
- PKD1L2 | n.1124G>A | RNA (SNP) | VAF 39/61 reads (64%) | catalogued as rs373030448; called by muse, mutect2, varscan2
- PLEC | c.524-5171T>G | Intron (SNP) | VAF 6/66 reads (9%) | catalogued as COSV100519931; called by muse, mutect2
- PREX2 | c.2716-2968C>T | Intron (SNP) | VAF 20/109 reads (18%) | catalogued as COSV99910569; called by muse, mutect2, varscan2
- PRG4 | c.-2C>T | 5'UTR (SNP) | VAF 13/52 reads (25%) | catalogued as rs139171967; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-23766A>T | Intron (SNP) | VAF 6/20 reads (30%) | catalogued as COSV101045350; called by muse, varscan2
- THRB | c.284-12662A>T | Intron (SNP) | VAF 9/44 reads (20%) | catalogued as COSV99769852; called by muse, mutect2, varscan2
